TCGA case TCGA-AC-A2FE — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6eebd4b-b63a-4a9c-92d3-0d954a8a6655

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Dead; Days to death: 2,636 days (7.2 years).

Diagnoses (3)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,746 days); Year of diagnosis: 2005; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 18; Lymph nodes tested: 18; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Days to treatment start: 67 days; Days to treatment end: 173 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride + Paclitaxel; Days to treatment start: 67 days; Days to treatment end: 173 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 178 days; Days to treatment end: 219 days; Treatment dose: 5,040 cGy; Treatment outcome: Partial Response; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Days to treatment start: 273 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 791 days (2.2 years); Days to treatment end: 813 days (2.2 years); Treatment outcome: Partial Response; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Nab-paclitaxel; Days to treatment start: 2,516 days (6.9 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Metastasis of diagnosis 1 (Lobular carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 64.4 years (23,512 days); Days to diagnosis: 766 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Lobular carcinoma, NOS), site: Liver. Age at diagnosis: 69.1 years (25,242 days); Days to diagnosis: 2,496 days (6.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Day 766 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 766 days (2.1 years).
- Days to follow up: 791 days (2.2 years); Disease response: With Tumor.
- Days to follow up: 2,240 days (6.1 years); Disease response: With Tumor.
- Day 2,496 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 2,496 days (6.8 years).
- Days to follow up: 2,636 days (7.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- ESR1 (IHC): Positive; Test value range: 60-69%.
- PGR (IHC): Positive; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AC-A2FE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-AC-A2FE-01A-01-TSA: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 75; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AC-A2FE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AC-A2FE-11B: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-AC-A2FE-11B-02-TS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AC-A2FE-11B-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Margin status: Negative; Method initial path diagnosis: Fine needle aspiration biopsy; Prospective collection: No; Retrospective collection: Yes; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Pharmaceutical therapy drug name: Arimidex.
- Drug treatment 4: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 5: Pharmaceutical therapy drug name: Xeloda; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Pharmaceutical therapy drug name: Abraxane; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,636 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,636 days; disease-free interval: event (new tumor event after initially disease-free), 766 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 766 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AC-A2FE-01A-11D-A19X-01): tumor purity 0.37, ploidy 2.06, whole-genome doublings 0.
